Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A7PW, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A7PW-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: Tumor occupies bladder wall. It is invasive and protruded, ill - margins with 7x5x5cm in size, necrotic, soft and gray surface.

Microscopic Description: Tumor is ulcerated and necrotic. Tumor cells are hyperplastic to arrange to form sheets or nest or groups or cords one by one. Tumor cells have moderate and eosinophilic. Nuclei are very enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are common. Tumor invades in fat tissue and vessel.

Diagnosis Details: Infiltrating urothelial carcinoma, high-grade, infiltrating in fat tissue

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 7 x 5 x 5 cm

Tumor features: Ulcerated

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Perivesical tissue (microscopic)

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, transitional cell NOS
8/20/13
Site Bladder NOS
C67.9
JW 9/12/13

Source: NCI Genomic Data Commons file f8e7b3a8-8881-43c0-9113-f0ca1759b44a (TCGA-E7-A7PW.7C70BB37-3B12-4980-A232-20E47478BE78.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).